Somatic mutation profile of tumor specimen MMRF_1951_1_BM_CD138pos (aliquot MMRF_1951_1_BM_CD138pos_T1_KBS5U_L06434) from MMRF case MMRF_1951, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.8 years (28,406 days).
Specimen MMRF_1951_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5095d4d1-73c2-4c04-ad37-3c45e63ae39d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1951_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1951_1_PB_Whole_C3_KBS5U_L06479; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4dd487f-d693-45ef-94ae-a3125ae8648d

The open-access MAF lists 336 somatic variants for this specimen: 135 protein-altering or splice-affecting, 45 silent, 156 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, 3'UTR 78, Silent 45, Intron 42, 5'UTR 19, 5'Flank 10, Nonsense Mutation 8, Frame Shift Del 5, 3'Flank 4, RNA 3, Splice Region 3, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.12488A>G p.N4163S | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs954366121; called by muse, mutect2
- ADAMTS20 | c.5450C>T p.T1817M | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs770174733, COSV67125728; called by muse, mutect2, varscan2
- AGTR1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.6); PolyPhen benign (0.058); catalogued as COSV100836893; called by muse, mutect2, varscan2
- ANKFN1 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.21); PolyPhen benign (0.421); catalogued as rs1461192422; called by muse, mutect2, varscan2
- ARHGEF25 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV99677578; called by muse, mutect2, varscan2
- ASH1L | c.8593G>A p.E2865K (on ENST00000368346 / NM_001366177.2; = p.E2860K on NM_018489.3) | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.971); catalogued as rs148152776, COSV64212070; called by muse, mutect2, varscan2
- ATP2C2 | c.2353G>A p.D785N | Missense Mutation (SNP) | VAF 128/286 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs769535560, COSV52301999; called by muse, mutect2
- AUTS2 | c.3481G>A p.D1161N | Missense Mutation (SNP) | VAF 110/233 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs911635138; called by muse, varscan2
- CACNA1A | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV64203582; called by muse, varscan2
- CACNA1A | c.2905G>A p.G969R | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as rs1473069840; called by muse, varscan2
- CLIP1 | c.586A>T p.I196F | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV56807946; called by muse, mutect2, varscan2
- COMTD1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV53685317; called by muse, mutect2, varscan2
- CPA6 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52721227; called by muse, mutect2, varscan2
- CTR9 | c.3176C>T p.S1059F | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63728920; called by muse, mutect2, varscan2
- DIAPH1 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs771016727; called by muse, mutect2, varscan2
- DIP2C | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs965093390; called by muse, mutect2, varscan2
- DLX1 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 221/496 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.432); catalogued as COSV59394389; called by muse, mutect2, varscan2
- DVL1 | c.1049C>G p.P350R | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1347984404; called by muse, mutect2, varscan2
- FLT1 | c.3354G>C p.R1118S | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99165532; called by muse, mutect2, varscan2
- FRMPD2 | c.1661C>T p.S554L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV59716586; called by muse, mutect2, varscan2
- GMEB2 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); catalogued as rs767176532; called by muse, mutect2
- GRM1 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 15/320 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51154535; called by muse, mutect2
- GRM6 | c.1615C>T p.H539Y | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.403); catalogued as rs1380815515, COSV99179628; called by muse, mutect2, varscan2
- HAUS6 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs750003005, COSV65839848; called by muse, mutect2, varscan2
- HECTD4 | c.5758G>A p.D1920N | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs770457144; called by muse, mutect2, varscan2
- IGLON5 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.125); catalogued as rs1478891688, COSV54536011; called by muse, mutect2, varscan2
- IQCA1 | c.1249C>G p.Q417E | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV54512180; called by muse, mutect2, varscan2
- IRF6 | c.1161G>C p.R387S | Missense Mutation (SNP) | VAF 93/425 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV65420471; called by muse, mutect2, varscan2
- ITGA11 | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1444906168, COSV59879909; called by muse, mutect2, varscan2
- ITGB2 | c.2341G>A p.A781T (on ENST00000302347; = p.A757T on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 141/357 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1421408165, COSV56610791; called by muse, mutect2, varscan2
- JARID2 | c.1577C>G p.S526C | Missense Mutation (SNP) | VAF 132/264 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs778974432, COSV59194091; called by muse, mutect2, varscan2
- KDM5C | c.4220A>G p.D1407G | Missense Mutation (SNP) | VAF 165/344 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64766572; called by muse, mutect2, varscan2
- KLF14 | c.115G>C p.A39P | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV60589024; called by muse, varscan2
- KMT2A | c.2576C>T p.S859F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV63292618; called by muse, mutect2, varscan2
- KRT75 | c.499-1G>A p.X167_splice | Splice Site (SNP) | VAF 35/59 reads (59%) | catalogued as rs541672130; called by muse, mutect2, varscan2
- KRTAP6-3 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | PolyPhen possibly damaging (0.448); catalogued as rs1181455960; called by muse, mutect2, varscan2
- LAMB2 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 95/194 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs369040269; called by muse, mutect2, varscan2
- LTN1 | c.1720C>G p.L574V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs747948331; called by muse, mutect2, varscan2
- MAIP1 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as rs752672763; called by muse, mutect2, varscan2
- MAX | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 92/103 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV52416961; called by muse, varscan2
- MYH6 | c.5768G>A p.R1923Q | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs757873491, COSV59305678; called by muse, mutect2, varscan2
- NAV1 | c.3500C>T p.S1167L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs932659518, COSV99818521; called by muse, mutect2, varscan2
- NFATC3 | c.1927C>G p.Q643E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV60475645; called by muse, mutect2, varscan2
- PCK1 | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1424827116; called by muse, mutect2, varscan2
- RNF17 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV55051714; called by muse, mutect2
- ROBO4 | c.3005C>G p.S1002C | Missense Mutation (SNP) | VAF 131/301 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as rs1384134902; called by muse, mutect2, varscan2
- RP1 | c.5913del p.N1971Kfs*6 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | catalogued as COSV55115958; called by mutect2, pindel, varscan2
- SUPT5H | c.2953C>A p.Q985K | Missense Mutation (SNP) | VAF 97/218 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV63241430; called by muse, mutect2, varscan2
- SVIL | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.7); catalogued as rs562741034, COSV100881516; called by muse, mutect2, varscan2
- TBX22 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV104428336, COSV64786940; called by muse, mutect2, varscan2
- TSPYL5 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 142/316 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs867103164, COSV100438937, COSV100439118; called by muse, mutect2, varscan2
- TTN | c.76762G>A p.E25588K (on ENST00000591111; = p.E18164K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | PolyPhen benign (0.124); catalogued as COSV100595031; called by muse, mutect2, varscan2
- TTYH3 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 143/330 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV51861011; called by muse, mutect2, varscan2
- VRK1 | c.22C>G p.Q8E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.084); catalogued as rs761254060; called by muse, mutect2, varscan2
- ZNF546 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV104416662; called by muse, mutect2, varscan2
- ZNF609 | c.3733C>T p.R1245W | Missense Mutation (SNP) | VAF 118/235 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1425968523; called by muse, mutect2, varscan2
- AASS | c.1000T>G p.F334V | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADPRM | c.977G>T p.R326I | Missense Mutation (SNP) | VAF 64/110 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ASIC1 | c.1297+3G>T | Splice Region (SNP) | VAF 85/182 reads (47%) | called by muse, mutect2, varscan2
- BHLHE41 | c.1005_1006del p.P336Lfs*163 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | called by pindel, varscan2*
- BMP6 | c.1281G>A p.Q427= | Splice Region (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- CACNA1F | c.2392G>C p.E798Q | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CARMIL3 | c.2456G>T p.G819V | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2
- CATSPER2 | c.233C>G p.S78* | Nonsense Mutation (SNP) | VAF 7/161 reads (4%) | called by muse, mutect2
- CBLL1 | c.878T>C p.I293T | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- CC2D1A | c.2711-1G>C p.X904_splice | Splice Site (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- CDC25C | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CFAP206 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CLRN2 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 87/185 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CPEB2 | c.3037G>T p.E1013* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- DDX18 | c.1175A>C p.K392T | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DDX20 | c.666C>G p.F222L | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- DIS3 | c.77G>C p.R26P | Missense Mutation (SNP) | VAF 78/81 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELK4 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 128/166 reads (77%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- EP300 | c.4776del p.E1593Rfs*5 | Frame Shift Del (DEL) | VAF 58/152 reads (38%) | called by mutect2, pindel, varscan2
- EXOSC9 | c.1174del p.S392Qfs*8 | Frame Shift Del (DEL) | VAF 55/130 reads (42%) | called by mutect2, pindel, varscan2
- FAM193A | c.2426G>C p.R809T | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAM214B | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 85/183 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBXW4 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 126/264 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCGBP | c.1252T>C p.F418L | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- GARNL3 | c.2476C>G p.Q826E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GCGR | c.1395G>T p.L465F | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- GPR156 | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- GRIN2A | c.3450del p.Y1151Tfs*17 | Frame Shift Del (DEL) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- HLA-DPA1 | c.346+4C>A | Splice Region (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- HS3ST2 | c.871_873del p.F291del | In Frame Del (DEL) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- IGHM | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 89/95 reads (94%) | SIFT tolerated (0.14); called by muse, mutect2
- IGHV3-64 | c.239A>T p.Y80F | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- IGLV8-61 | c.29T>A p.M10K | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- KIAA0100 | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KLF4 | c.212C>A p.A71D | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- LRRC20 | c.14T>G p.M5R | Missense Mutation (SNP) | VAF 111/220 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- LTBP1 | c.59C>A p.S20* | Nonsense Mutation (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MAPKAPK2 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MX1 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 38/84 reads (45%) | called by muse, mutect2, varscan2
- MYH1 | c.422C>G p.T141R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- NCKAP5L | c.1463G>A p.C488Y | Missense Mutation (SNP) | VAF 86/189 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- NFATC4 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NFKB2 | c.1168T>C p.S390P | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- NSD1 | c.4822C>G p.L1608V | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.082); called by muse, mutect2
- PDCD11 | c.4520G>A p.G1507E | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- PLA2G3 | c.293A>G p.H98R | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PLCXD3 | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- PLPP3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 7/180 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- PRR36 | c.2921C>T p.T974M | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PTGFRN | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RHD | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- RMC1 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 116/221 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPGR | c.1426G>C p.D476H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- RUBCN | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 64/119 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCRIB | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- SH2B1 | c.720G>C p.L240F | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLC44A1 | c.1907C>G p.A636G | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SRRM2 | c.4891G>A p.A1631T | Missense Mutation (SNP) | VAF 225/489 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ST3GAL3 | c.880G>T p.E294* (on ENST00000361392 / NM_174964.4; = p.E279* on NM_006279.5) | Nonsense Mutation (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- STAB1 | c.7573C>T p.P2525S | Missense Mutation (SNP) | VAF 294/654 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.837); called by muse, mutect2
- SYCP1 | c.938C>G p.S313* | Nonsense Mutation (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- SYNC | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYT17 | c.1090C>A p.Q364K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- TEP1 | c.7333G>C p.G2445R | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TEP1 | c.4985C>A p.T1662N | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- TERT | c.3374C>G p.S1125* | Nonsense Mutation (SNP) | VAF 46/108 reads (43%) | called by muse, mutect2, varscan2
- TMED7 | c.165G>C p.Q55H | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- UMODL1 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- USP31 | c.3684C>G p.F1228L | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- USP54 | c.3962C>G p.S1321C | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZBED9 | c.2596C>G p.Q866E | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- ZFAND4 | c.989A>G p.H330R | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF107 | c.1412A>G p.E471G | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF683 | c.878C>A p.S293Y | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2
- ZNF763 | c.827G>C p.R276T (on ENST00000358987 / NM_001367172.2; = p.R279T on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- ZNF841 | c.1490C>A p.S497* (on ENST00000426391 / NM_001369830.1; = p.S613* on NM_001136499.1 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 88/176 reads (50%) | called by muse, mutect2, varscan2
- ZSCAN16 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ACTRT2 | c.219C>T p.S73= | Silent (SNP) | VAF 160/308 reads (52%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.2352G>A p.Q784= | Silent (SNP) | VAF 12/304 reads (4%) | called by muse, mutect2
- ANKIB1 | c.1338C>T p.L446= | Silent (SNP) | VAF 34/57 reads (60%) | catalogued as COSV56061325, COSV56061993; called by muse, mutect2, varscan2
- ANO1 | c.660C>G p.L220= | Silent (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- ANO5 | c.111C>G p.T37= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV100201469; called by muse, mutect2, varscan2
- AP002512.3 | c.594G>T p.V198= | Silent (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- APBB2 | c.75C>T p.D25= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs1338321948; called by muse, mutect2, varscan2
- APOA1 | c.33C>G p.L11= | Silent (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- ARHGEF11 | c.711G>A p.L237= | Silent (SNP) | VAF 69/171 reads (40%) | called by muse, mutect2, varscan2
- ATP6V0D2 | c.405C>T p.F135= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs772983464; called by muse, mutect2, varscan2
- CFAP57 | c.1086C>G p.L362= | Silent (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- CRTC3 | c.1017G>A p.K339= | Silent (SNP) | VAF 11/338 reads (3%) | called by muse, mutect2
- ERVFRD-1 | c.663C>G p.L221= | Silent (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- ETS1 | c.159C>T p.F53= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV60098100; called by muse, mutect2, varscan2
- FAM174B | c.273C>G p.L91= | Silent (SNP) | VAF 73/138 reads (53%) | called by muse, mutect2, varscan2
- GATAD2B | c.1554C>T p.L518= | Silent (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- GLIS2 | c.408C>T p.L136= | Silent (SNP) | VAF 138/331 reads (42%) | catalogued as rs773863545, COSV52111385; called by muse, mutect2, varscan2
- GRIA4 | c.351C>T p.L117= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs1194970445; called by muse, mutect2, varscan2
- HRH1 | c.348C>T p.F116= | Silent (SNP) | VAF 72/154 reads (47%) | catalogued as COSV101229087; called by muse, mutect2, varscan2
- ICAM3 | c.1137C>G p.L379= | Silent (SNP) | VAF 101/205 reads (49%) | catalogued as COSV99348938; called by muse, mutect2, varscan2
- INSIG1 | c.51G>A p.A17= | Silent (SNP) | VAF 201/419 reads (48%) | catalogued as COSV100453000; called by muse, mutect2, varscan2
- MUC16 | c.33828T>C p.T11276= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs1156708209; called by muse, mutect2, varscan2
- MYO15A | c.825C>T p.G275= | Silent (SNP) | VAF 201/218 reads (92%) | catalogued as rs376641289; called by muse, mutect2, varscan2
- NTRK3 | c.1464C>T p.I488= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV58151667; called by muse, mutect2, varscan2
- NUP188 | c.4998G>A p.A1666= | Silent (SNP) | VAF 21/462 reads (5%) | catalogued as rs772946032, COSV65330304; called by muse, mutect2
- OR51G2 | c.75G>A p.L25= | Silent (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- OTOG | c.3423C>A p.G1141= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as COSV61128646; called by muse, mutect2, varscan2
- PCDHB12 | c.1245C>T p.A415= | Silent (SNP) | VAF 102/213 reads (48%) | catalogued as rs781988261; called by muse, mutect2, varscan2
- PLD1 | c.1149G>C p.L383= | Silent (SNP) | VAF 47/98 reads (48%) | called by muse, mutect2, varscan2
- PNPLA2 | c.1281C>G p.L427= | Silent (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- RBFOX2 | c.726C>T p.H242= (on ENST00000438146 / NM_001349995.2; = p.H172= on NM_014309.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as rs764510203; ClinVar: likely benign; called by muse, mutect2
- RNF139 | c.588G>A p.V196= | Silent (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- SCML4 | c.324C>G p.P108= | Silent (SNP) | VAF 9/119 reads (8%) | catalogued as COSV64635765; called by muse, mutect2
- SEMA4D | c.1008C>G p.V336= | Silent (SNP) | VAF 84/172 reads (49%) | called by muse, mutect2
- SLC26A9 | c.1116C>G p.L372= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV61602116; called by muse, mutect2, varscan2
- SPAG1 | c.1165C>T p.L389= | Silent (SNP) | VAF 60/139 reads (43%) | catalogued as rs1031068025; called by muse, mutect2, varscan2
- SRCAP | c.3723C>T p.L1241= | Silent (SNP) | VAF 124/237 reads (52%) | catalogued as COSV52674300; called by muse, mutect2, varscan2
- TIGD3 | c.1266G>A p.E422= | Silent (SNP) | VAF 78/158 reads (49%) | called by muse, mutect2, varscan2
- TMEM170B | c.84G>A p.L28= | Silent (SNP) | VAF 103/221 reads (47%) | called by muse, mutect2, varscan2
- TRAV24 | c.72G>A p.L24= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs1471971614; called by muse, mutect2, varscan2
- TSPEAR | c.342C>T p.S114= | Silent (SNP) | VAF 8/182 reads (4%) | catalogued as rs782682429; called by muse, mutect2
- UGT2B4 | c.1524C>T p.I508= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV59315141; called by muse, mutect2, varscan2
- UXS1 | c.72C>A p.I24= | Silent (SNP) | VAF 38/68 reads (56%) | called by muse, mutect2, varscan2
- WASHC5 | c.666C>T p.I222= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs367837906; ClinVar: likely benign; called by muse, mutect2, varscan2
- YARS1 | c.300G>A p.V100= | Silent (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- AC092377.1 | chr16:85357532 C>T | 5'Flank (SNP) | VAF 47/110 reads (43%) | catalogued as rs374652358; called by muse, mutect2, varscan2
- ACAD8 | c.1195+1008G>T | Intron (SNP) | VAF 51/117 reads (44%) | called by muse, mutect2, varscan2
- ACTR3C | c.*38+338C>G | Intron (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
- ADAM33 | c.334-34G>T | Intron (SNP) | VAF 90/203 reads (44%) | called by muse, mutect2, varscan2
- ADRA2B | c.-108C>T | 5'UTR (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- AGFG2 | c.*778C>G | 3'UTR (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2, varscan2
- AKAP7 | c.850+30469C>T | Intron (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- ANKH | c.-98C>T | 5'UTR (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- ANKRD36 | c.-79C>G | 5'UTR (SNP) | VAF 65/142 reads (46%) | catalogued as COSV101347233; called by muse, mutect2, varscan2
- ANKS6 | c.*1312G>C | 3'UTR (SNP) | VAF 88/168 reads (52%) | called by muse, mutect2, varscan2
- ANP32E | c.*918G>A | 3'UTR (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.836-969C>A | Intron (SNP) | VAF 132/310 reads (43%) | called by muse, varscan2
- ARIH2 | chr3:48918278 C>T | 5'Flank (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- ASB13 | c.*88G>A | 3'UTR (SNP) | VAF 49/110 reads (45%) | called by muse, mutect2, varscan2
- BFAR | c.*152C>G | 3'UTR (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- BOD1L1 | c.*346C>T | 3'UTR (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- BSDC1 | c.*285G>A | 3'UTR (SNP) | VAF 166/388 reads (43%) | called by muse, mutect2, varscan2
- BTBD7 | c.*3200C>T | 3'UTR (SNP) | VAF 39/64 reads (61%) | called by muse, mutect2, varscan2
- C2CD2L | c.*1621C>T | 3'UTR (SNP) | VAF 52/95 reads (55%) | catalogued as rs1029777762; called by muse, mutect2, varscan2
- CAAP1 | c.*519G>A | 3'UTR (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- CACYBP | c.*447G>C | 3'UTR (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- CAGE1 | c.-90C>T | 5'UTR (SNP) | VAF 183/410 reads (45%) | called by muse, mutect2, varscan2
- CAPN2 | c.-9G>A | 5'UTR (SNP) | VAF 24/147 reads (16%) | catalogued as rs1377726716; called by muse, mutect2, varscan2
- CARF | c.*389G>A | 3'UTR (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- CBFA2T3 | c.*445C>T | 3'UTR (SNP) | VAF 81/160 reads (51%) | called by muse, mutect2, varscan2
- CCER1 | c.-298C>T | 5'UTR (SNP) | VAF 48/98 reads (49%) | called by muse, mutect2
- CCND2 | c.*2083C>G | 3'UTR (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- CD86 | c.*471G>A | 3'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- CDCA5 | c.-11G>A | 5'UTR (SNP) | VAF 110/274 reads (40%) | catalogued as rs765642943; called by muse, mutect2, varscan2
- CDHR5 | c.*478C>G | 3'UTR (SNP) | VAF 166/530 reads (31%) | called by muse, mutect2, varscan2
- CEP78 | c.*191C>T | 3'UTR (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- CHCHD5 | c.310-129G>A | Intron (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- CHID1 | chr11:914512 C>T | 5'Flank (SNP) | VAF 46/137 reads (34%) | called by muse, mutect2, varscan2
- CHRNA7 | c.*594A>C | 3'UTR (SNP) | VAF 98/326 reads (30%) | called by mutect2, varscan2
- CHTOP | c.404-318G>C | Intron (SNP) | VAF 26/104 reads (25%) | called by muse, mutect2, varscan2
- CLNK | c.*951A>G | 3'UTR (SNP) | VAF 14/32 reads (44%) | catalogued as rs1285802731; called by muse, mutect2, varscan2
- CNTN2 | c.2844+107T>A | Intron (SNP) | VAF 33/116 reads (28%) | called by muse, mutect2, varscan2
- COL6A2 | c.2462-2610G>A | Intron (SNP) | VAF 13/347 reads (4%) | catalogued as rs1296636879; called by muse, mutect2
- CPD | c.*2696C>G | 3'UTR (SNP) | VAF 22/34 reads (65%) | called by muse, mutect2, varscan2
- CRISP2 | c.*187G>A | 3'UTR (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- CTNND2 | c.*836G>A | 3'UTR (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- DNAL1 | c.*722C>G | 3'UTR (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- DOCK8 | chr9:214809 C>A | 5'Flank (SNP) | VAF 116/271 reads (43%) | called by muse, mutect2, varscan2
- DUSP7 | c.*1494G>C | 3'UTR (SNP) | VAF 90/214 reads (42%) | called by muse, mutect2, varscan2
- EN1 | c.*485C>T | 3'UTR (SNP) | VAF 77/160 reads (48%) | called by muse, mutect2, varscan2
- ENOX2 | c.*1483dup | 3'UTR (INS) | VAF 35/70 reads (50%) | called by mutect2, pindel, varscan2
- ENTPD1 | c.1075-41C>G | Intron (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- ERBB4 | c.*3000G>A | 3'UTR (SNP) | VAF 7/19 reads (37%) | called by mutect2, varscan2
- FAM207A | chr21:44939596 C>T | 5'Flank (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- FCRL6 | c.320-76G>C | Intron (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- FNBP1L | c.*2003G>A | 3'UTR (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- FOXJ3 | c.*491G>A | 3'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2
- GLOD4 | c.675+109A>G | Intron (SNP) | VAF 25/26 reads (96%) | called by muse, mutect2, varscan2
- GLYCTK | chr3:52287097 G>C | 5'Flank (SNP) | VAF 117/278 reads (42%) | called by muse, mutect2, varscan2
- GNL1 | c.*1265C>T | 3'UTR (SNP) | VAF 35/36 reads (97%) | called by muse, mutect2, varscan2
- H6PD | c.*5911G>A | 3'UTR (SNP) | VAF 13/191 reads (7%) | called by muse, mutect2
- HECA | c.-268C>T | 5'UTR (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- HELLS | c.1851+27T>C | Intron (SNP) | VAF 30/60 reads (50%) | catalogued as rs1289306392; called by muse, mutect2, varscan2
- HMGN2 | c.90+118T>G | Intron (SNP) | VAF 49/110 reads (45%) | catalogued as rs550079083; called by muse, mutect2, varscan2
- HMMR | chr5:163460275 G>T | 5'Flank (SNP) | VAF 45/94 reads (48%) | called by muse, mutect2, varscan2
- HOXD3 | chr2:176173389 G>C | 3'Flank (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
- HS3ST3B1 | c.*24C>A | 3'UTR (SNP) | VAF 293/727 reads (40%) | called by muse, mutect2, varscan2
- HS3ST3B1 | c.*624G>C | 3'UTR (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- IGLV3-21 | c.-49A>T | 5'UTR (SNP) | VAF 18/18 reads (100%) | called by muse, mutect2, varscan2
- IRF2BP2 | c.*1545C>G | 3'UTR (SNP) | VAF 11/231 reads (5%) | called by muse, mutect2
- ITGA3 | c.1537+30T>C | Intron (SNP) | VAF 154/346 reads (45%) | catalogued as rs1300880370; called by muse, mutect2, varscan2
- ITGA5 | c.*3C>T | 3'UTR (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- KCNIP4 | c.62-101189G>A | Intron (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
- KCNK13 | c.-156C>G | 5'UTR (SNP) | VAF 55/126 reads (44%) | called by muse, mutect2, varscan2
- KDM4B | c.1115+991C>T | Intron (SNP) | VAF 101/221 reads (46%) | called by muse, mutect2, varscan2
- KIDINS220 | c.3528+49G>C | Intron (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- KLRD1 | c.*663G>A | 3'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- KRBA1 | c.*37G>A | 3'UTR (SNP) | VAF 27/66 reads (41%) | catalogued as rs970147554; called by muse, mutect2, varscan2
- LARS2 | c.*2080G>A | 3'UTR (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- LETMD1 | c.274+9G>A | Intron (SNP) | VAF 139/235 reads (59%) | called by muse, mutect2, varscan2
- LINC01600 | n.836C>T | RNA (SNP) | VAF 26/67 reads (39%) | catalogued as rs753536022; called by muse, mutect2, varscan2
- LRATD1 | c.*2821C>G | 3'UTR (SNP) | VAF 48/100 reads (48%) | called by muse, mutect2, varscan2
- LSM14B | c.-149C>T | 5'UTR (SNP) | VAF 8/26 reads (31%) | catalogued as rs1053909285; called by muse, varscan2
- MARK4 | c.1494+34del | Intron (DEL) | VAF 203/497 reads (41%) | catalogued as rs1257399838; called by mutect2, pindel, varscan2
- MELTF | c.*593G>A | 3'UTR (SNP) | VAF 8/21 reads (38%) | catalogued as rs527307360; called by muse, varscan2
- MEOX2 | c.*316A>T | 3'UTR (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2, varscan2
- MPZ | c.585-18_585-16del | Intron (DEL) | VAF 428/640 reads (67%) | called by pindel, varscan2
- MTMR1 | c.253-5659G>A | Intron (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- MTMR3 | c.1504-92C>T | Intron (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2
- MTMR9 | c.1334+1217G>C | Intron (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- MTO1 | c.*8245G>A | 3'UTR (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- MTTP | c.*295G>A | 3'UTR (SNP) | VAF 8/19 reads (42%) | catalogued as rs1218534477; called by mutect2, varscan2
- MTURN | c.*3068A>T | 3'UTR (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- MX2 | c.*776G>A | 3'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- NAGPA | c.792-57G>A | Intron (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- NCLN | c.1632+19C>T | Intron (SNP) | VAF 70/132 reads (53%) | catalogued as rs973677464; called by muse, mutect2, varscan2
- NEB | c.8890-431C>T | Intron (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- NEMP2 | c.*4584_*4591del | 3'UTR (DEL) | VAF 18/47 reads (38%) | called by mutect2, pindel, varscan2
- NLGN1 | c.*2377C>G | 3'UTR (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- NSL1 | c.*11507G>C | 3'UTR (SNP) | VAF 129/268 reads (48%) | called by muse, mutect2, varscan2
- OPRK1 | c.*1327G>A | 3'UTR (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- ORC6 | c.563-99G>C | Intron (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- PALLD | c.*1611G>A | 3'UTR (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- PAPPA2 | c.2431+52G>C | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- PCBP3 | c.*666C>T | 3'UTR (SNP) | VAF 35/61 reads (57%) | called by muse, mutect2, varscan2
- PCDH19 | c.*1355A>C | 3'UTR (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- PLAAT3 | chr11:63614465 C>T | 5'Flank (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- PLEKHM3 | c.1950+7369G>C | Intron (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*2182G>C | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- PMPCA | c.1263+20A>T | Intron (SNP) | VAF 85/199 reads (43%) | called by muse, mutect2, varscan2
- PNPLA2 | c.*13C>G | 3'UTR (SNP) | VAF 162/327 reads (50%) | called by muse, mutect2, varscan2
- POMT1 | c.*279G>A | 3'UTR (SNP) | VAF 78/144 reads (54%) | catalogued as rs1008129269; called by mutect2, varscan2
- PPARA | c.*4600C>G | 3'UTR (SNP) | VAF 94/182 reads (52%) | catalogued as rs1267986966; called by muse, mutect2, varscan2
- PPIP5K2 | c.-397G>A | 5'UTR (SNP) | VAF 34/63 reads (54%) | called by muse, mutect2, varscan2
- RBBP4 | c.*1112C>T | 3'UTR (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- RBBP4 | c.*1621C>T | 3'UTR (SNP) | VAF 14/35 reads (40%) | catalogued as rs574275577; called by muse, mutect2, varscan2
- RBM43 | c.-22G>A | 5'UTR (SNP) | VAF 117/239 reads (49%) | called by muse, varscan2
- REC8 | c.-235G>A | 5'UTR (SNP) | VAF 132/261 reads (51%) | catalogued as rs1411742689; called by muse, mutect2, varscan2
- RESF1 | c.*493G>A | 3'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- RHPN2P1 | n.1728G>A | RNA (SNP) | VAF 23/80 reads (29%) | catalogued as rs1355826354; called by muse, mutect2, varscan2
- RNASE7 | c.*730C>A | 3'UTR (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- RNF121 | c.762-74G>C | Intron (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- RPL34 | c.-9-68G>C | Intron (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- SCAF11 | c.-21-11043C>T | Intron (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- SCAMP4 | c.-42+150C>T | Intron (SNP) | VAF 16/27 reads (59%) | called by muse, mutect2, varscan2
- SCO1 | c.*225G>A | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- SH2D1A | c.*568G>A | 3'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- SHISAL2B | c.-110C>T | 5'UTR (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2, varscan2
- SIDT2 | c.*733C>G | 3'UTR (SNP) | VAF 99/203 reads (49%) | called by muse, mutect2, varscan2
- SIKE1 | c.*491C>T | 3'UTR (SNP) | VAF 46/79 reads (58%) | called by muse, mutect2, varscan2
- SKI | c.*1972C>T | 3'UTR (SNP) | VAF 141/276 reads (51%) | catalogued as rs929257778; called by muse, mutect2, varscan2
- SLC11A1 | c.*1018G>A | 3'UTR (SNP) | VAF 86/182 reads (47%) | called by muse, mutect2, varscan2
- SLC5A6 | chr2:27212924 G>A | 5'Flank (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- SLITRK4 | chrX:143623434 C>T | 3'Flank (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- SMARCB1 | c.491-78G>A | Intron (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- SNORD116-16 | n.71C>T | RNA (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- SNX1 | chr15:64145938 G>A | 3'Flank (SNP) | VAF 64/132 reads (48%) | called by muse, mutect2, varscan2
- SOX10 | c.*1170A>G | 3'UTR (SNP) | VAF 186/400 reads (47%) | called by muse, mutect2, varscan2
- SPRED1 | c.*4508C>T | 3'UTR (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- SRD5A1 | c.-90C>T | 5'UTR (SNP) | VAF 73/138 reads (53%) | called by muse, mutect2, varscan2
- SRSF11 | c.*1751A>G | 3'UTR (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- SRSF7 | chr2:38751365 G>A | 5'Flank (SNP) | VAF 174/350 reads (50%) | catalogued as rs1206678436, COSV100492536, COSV100492551; called by muse, mutect2, varscan2
- STUM | c.*1406C>A | 3'UTR (SNP) | VAF 31/157 reads (20%) | called by muse, mutect2, varscan2
- SUGP2 | c.-82C>T | 5'UTR (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- TBXAS1 | c.451-794G>C | Intron (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- TFPI2 | c.*118T>G | 3'UTR (SNP) | VAF 33/55 reads (60%) | called by muse, mutect2
- TMPRSS13 | chr11:117900722 G>C | 3'Flank (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- TNNT2 | c.41+87G>A | Intron (SNP) | VAF 181/264 reads (69%) | catalogued as rs745752780; called by muse, mutect2, varscan2
- TP53I11 | c.*2093C>T | 3'UTR (SNP) | VAF 151/318 reads (47%) | called by muse, mutect2, varscan2
- TRIM62 | c.*1414G>C | 3'UTR (SNP) | VAF 53/104 reads (51%) | called by muse, mutect2, varscan2
- UBE2K | c.*2126C>T | 3'UTR (SNP) | VAF 32/58 reads (55%) | called by muse, mutect2, varscan2
- USP42 | c.442+1242C>T | Intron (SNP) | VAF 133/270 reads (49%) | called by muse, mutect2, varscan2
- WDPCP | c.500-322C>G | Intron (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- WDR41 | c.*2126C>G | 3'UTR (SNP) | VAF 46/112 reads (41%) | called by muse, mutect2, varscan2
- WDR73 | c.353-136C>T | Intron (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2
- WDR91 | c.*1965del | 3'UTR (DEL) | VAF 127/294 reads (43%) | called by mutect2, pindel, varscan2
- WSB1 | c.-89A>C | 5'UTR (SNP) | VAF 118/238 reads (50%) | called by muse, mutect2, varscan2
- YARS1 | c.-826G>A | 5'UTR (SNP) | VAF 33/66 reads (50%) | called by muse, mutect2, varscan2
- YKT6 | c.*398G>A | 3'UTR (SNP) | VAF 14/38 reads (37%) | catalogued as rs1439572631; called by muse, mutect2, varscan2
- YPEL4 | c.185+62C>T | Intron (SNP) | VAF 143/271 reads (53%) | catalogued as COSV55519124; called by muse, mutect2, varscan2
- ZNF451 | c.*929C>T | 3'UTR (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
